FM case AD15002 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vulva.
https://portal.gdc.cancer.gov/cases/3ad895a5-765f-4412-944f-d2bbaae1de05

Female, 50.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vulva; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Metastatic.
